FM case AD9400 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms.
https://portal.gdc.cancer.gov/cases/6efb2684-2f47-4728-889f-20b05edf00ef

Female, 46.8 years: Myoepithelial carcinoma (ICD-O-3 8982/3); specimen biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
